Gene-level copy-number profile of specimen HCM-BROD-0230-C25-85D from HCMI case HCM-BROD-0230-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 83.0 years (30,305 days).
Specimen HCM-BROD-0230-C25-85D: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6946ccf0-2fa9-4f96-bb44-b3123a2c8341.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0230-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/a5521b79-b11b-4ecb-9412-d349ad98c26a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 14,626; copy number 2: 37,024; copy number 3: 4,671; copy number 4: 1,344; copy number 5: 1,159; copy number 6: 51; copy number 7: 3; copy number 8: 6; copy number 9: 18.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:184,334,292–184,382,416, 2 genes: LINC02363, LINC02362.
- chr9:61,581,813–61,662,690, 4 genes: AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr12:47,882,649–47,901,525, 1 gene (within-gene range 0–1): AC121338.1.
- chr12:52,689,626–52,703,524, 2 genes: KRT77, AC055716.3.
- chr13:57,204,379–57,204,799, 1 gene: MTCO2P3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,237 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,846,504, 21 genes, copy number 7–9: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2.
- chr1:189,666,149–248,937,043, 1,190 genes, copy number 5–8 (broad region; genes not listed).
- chr21:7,744,962–8,454,792, 26 genes, copy number 5: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.

Autosomal genes at a single copy (total copy number 1): 11,770. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
